Somatic mutation profile of tumor specimen TARGET-40-NAAHBJ-01A (aliquot TARGET-40-NAAHBJ-01A-01D) from TARGET case TARGET-40-NAAHBJ, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 18.3 years (6,689 days).
Specimen TARGET-40-NAAHBJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7cde5878-fe3c-4443-ab1e-a09924ac20df.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAHBJ-10A (Blood Derived Normal), aliquot TARGET-40-NAAHBJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0e97e83-044c-4772-b839-a2b9ae73829d

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYNC1H1 | c.13123G>T p.A4375S | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as rs1472613465; called by muse, mutect2, varscan2
- RNF10 | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1225927472; called by muse, mutect2, varscan2
- VPS13A | c.3890G>T p.R1297L | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV62437861; called by muse, varscan2
- ABCA5 | c.1513T>A p.Y505N | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH9 | c.6263C>T p.P2088L | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- LAMA1 | c.1949G>A p.S650N | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VPS13A | c.3958G>C p.E1320Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.582); called by muse, varscan2
- SRRT | c.2429-14G>T | Intron (SNP) | VAF 11/68 reads (16%) | called by muse, mutect2, varscan2
